Somatic mutation profile of tumor specimen ALCH-B35S-TTP1-A (aliquot ALCH-B35S-TTP1-A-1-0-D-A78R-36) from ALCHEMIST case ALCH-B35S, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 69.0 years (25,208 days).
Specimen ALCH-B35S-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c86bbb32-3505-475b-a8d2-b02f70ec8613.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B35S-NB1-A (Blood Derived Normal), aliquot ALCH-B35S-NB1-A-1-0-D-A78R-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e95bdf44-f0b8-4310-b0de-d3de83020ee2

The open-access MAF lists 31 somatic variants for this specimen: 23 protein-altering or splice-affecting, 4 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 4, Nonsense Mutation 4, Intron 2, Splice Region 1, RNA 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNAS | c.601C>T p.R201C | Missense Mutation (SNP) | VAF 127/870 reads (15%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as rs11554273, COSV55670339, COSV55670675, COSV55677163; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KLF4 | c.1225A>C p.K409Q | Missense Mutation (SNP) | VAF 49/413 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as COSV65928521; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 103/736 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ATP11B | c.892A>G p.I298V | Missense Mutation (SNP) | VAF 49/285 reads (17%) | SIFT tolerated (0.59); PolyPhen benign (0.043); catalogued as rs780195900; called by muse, mutect2, varscan2
- NFXL1 | c.1571T>C p.V524A | Missense Mutation (SNP) | VAF 53/394 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.019); catalogued as COSV61199494; called by muse, mutect2, varscan2
- NKX2-1 | c.163C>T p.Q55* | Nonsense Mutation (SNP) | VAF 9/56 reads (16%) | catalogued as CM146078; called by muse, mutect2, varscan2
- NOS1AP | c.1265G>A p.R422H | Missense Mutation (SNP) | VAF 24/231 reads (10%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.075); catalogued as COSV62640906; called by muse, mutect2, varscan2
- OR2C3 | c.953C>T p.A318V | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.001); catalogued as rs147306837, COSV63574800; called by muse, varscan2
- QRSL1 | c.555C>T p.Y185= | Splice Region (SNP) | VAF 28/131 reads (21%) | catalogued as rs763443331, COSV64688016; called by muse, varscan2
- RHOBTB1 | c.129T>G p.Y43* | Nonsense Mutation (SNP) | VAF 23/246 reads (9%) | catalogued as COSV100558561; called by muse, mutect2
- RIMS2 | c.2117G>A p.R706H (on ENST00000666250 / NM_001348490.2; = p.R514H on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 52/640 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as rs754256738, COSV51679147, COSV99154333; called by muse, mutect2
- SLC9A4 | c.1970G>A p.R657H | Missense Mutation (SNP) | VAF 36/374 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.259); catalogued as rs1183527125, COSV54836879; called by muse, mutect2
- TM2D1 | c.17C>T p.P6L | Missense Mutation (SNP) | VAF 38/164 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.011); catalogued as rs751636109; called by muse, mutect2, varscan2
- ADGRD1 | c.1018C>G p.L340V | Missense Mutation (SNP) | VAF 34/391 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ATP2B1 | c.2632C>T p.Q878* | Nonsense Mutation (SNP) | VAF 112/583 reads (19%) | called by muse, mutect2, varscan2
- CFAP43 | c.2845A>C p.K949Q | Missense Mutation (SNP) | VAF 30/228 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.028); called by muse, mutect2
- CTSF | c.1272C>A p.C424* | Nonsense Mutation (SNP) | VAF 9/63 reads (14%) | called by muse, mutect2, varscan2
- GARNL3 | c.364T>C p.F122L | Missense Mutation (SNP) | VAF 65/587 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- GNAS | c.763A>G p.M255V | Missense Mutation (SNP) | VAF 74/698 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.477); called by muse, mutect2, varscan2
- NEMF | c.2330A>G p.Y777C | Missense Mutation (SNP) | VAF 50/282 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); called by mutect2, varscan2
- PXDNL | c.1494G>C p.K498N | Missense Mutation (SNP) | VAF 38/279 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- TDRD15 | c.4342G>T p.D1448Y | Missense Mutation (SNP) | VAF 49/223 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.788); called by muse, mutect2, varscan2
- TDRD7 | c.155A>T p.Y52F | Missense Mutation (SNP) | VAF 108/851 reads (13%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- C10orf71 | c.2631G>A p.R877= | Silent (SNP) | VAF 33/217 reads (15%) | catalogued as rs1438146637; called by muse, mutect2, varscan2
- HSF1 | c.1170T>A p.A390= | Silent (SNP) | VAF 27/127 reads (21%) | catalogued as COSV60047073; called by muse, mutect2, varscan2
- RBMXL2 | c.906C>T p.Y302= | Silent (SNP) | VAF 9/71 reads (13%) | catalogued as rs774916563, COSV100182057; called by muse, mutect2, varscan2
- WDR97 | c.4740G>A p.P1580= | Silent (SNP) | VAF 10/54 reads (19%) | called by muse, mutect2, varscan2
- AL359878.1 | n.380G>T | RNA (SNP) | VAF 105/635 reads (17%) | called by muse, mutect2, varscan2
- ANKRD24 | c.37-1503del | Intron (DEL) | VAF 4/36 reads (11%) | called by pindel, varscan2
- ARNT2 | chr15:80403576 G>A | 5'Flank (SNP) | VAF 71/336 reads (21%) | called by muse, mutect2, varscan2
- GPAM | c.2311+38_2311+39insA | Intron (INS) | VAF 30/228 reads (13%) | called by mutect2, pindel, varscan2
